Somatic mutation profile of tumor specimen e0068ac5-f557-443a-bd4b-bdfcef (aliquot e0068ac5-f557-443a-bd4b-bdfcef_D6) from CPTAC case 05CO028, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen e0068ac5-f557-443a-bd4b-bdfcef: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0535f9ad-a887-488a-9dfa-cabb85a2305b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 71116934-bfd8-4ecc-a6c1-ed0bff (Blood Derived Normal), aliquot 71116934-bfd8-4ecc-a6c1-ed0bff_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaa0803a-3055-4272-a633-57027096004a

The open-access MAF lists 231 somatic variants for this specimen: 151 protein-altering or splice-affecting, 52 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 52, Nonsense Mutation 14, Intron 12, Frame Shift Ins 5, 3'UTR 5, 5'Flank 5, RNA 3, Frame Shift Del 3, 3'Flank 2, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 62/238 reads (26%) | catalogued as rs775126020, CM980087, COSV57320525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 104/414 reads (25%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 155/559 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFIA | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 16/79 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as rs1553148514; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs779914905; called by muse, mutect2, varscan2
- AGT | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 184/808 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61762537; called by muse, mutect2, varscan2
- B3GALT5 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs372607334; called by muse, mutect2, varscan2
- BCLAF1 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 41/218 reads (19%) | catalogued as rs138333275, CM136163; called by muse, mutect2, varscan2
- C3orf84 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs754289775, COSV60412884; called by muse, mutect2, varscan2
- CCDC39 | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs998473653; called by muse, mutect2, varscan2
- CCL3L3 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 44/585 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1473476410; called by muse, mutect2
- CDH8 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.148); catalogued as rs1567404075, COSV100180310; called by muse, mutect2, varscan2
- CDH9 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 135/454 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755843215, COSV50260964; called by muse, mutect2, varscan2
- CHAF1A | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1440540090, COSV100010841, COSV100011137; called by muse, mutect2
- COL4A6 | c.4645G>A p.A1549T | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766360534, COSV57866479; called by muse, mutect2, varscan2
- COL5A1 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 124/429 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs770737485; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.454); catalogued as rs774800733, COSV62039398; called by muse, mutect2, varscan2
- CRYGS | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1384578760, COSV57192410; called by muse, mutect2
- DCAF4L2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 80/509 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs752302400, COSV60476978, COSV60484022; called by muse, mutect2, varscan2
- DCUN1D3 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 76/299 reads (25%) | catalogued as COSV60953014; called by muse, mutect2, varscan2
- DLK1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs781097687; called by muse, mutect2, varscan2
- ELMOD2 | c.589C>A p.H197N | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV100063013; called by muse, mutect2
- EMILIN1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as rs1353032940; called by muse, mutect2
- EPHA10 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs972379828; called by muse, mutect2
- EPHB4 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs767324545; called by muse, mutect2, varscan2
- EYA4 | c.887C>A p.S296* | Nonsense Mutation (SNP) | VAF 90/400 reads (23%) | catalogued as COSV62046101; called by mutect2, varscan2
- FAM90A1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 129/673 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.34); catalogued as rs780112980, COSV100274146; called by muse, mutect2, varscan2
- FEZF2 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV99334821; called by muse, mutect2, varscan2
- FUBP1 | c.901dup p.I301Nfs*4 | Frame Shift Ins (INS) | VAF 32/116 reads (28%) | catalogued as rs1200882279; called by mutect2, varscan2
- FXR1 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs746038547, COSV59762458; called by muse, mutect2, varscan2
- GABRR1 | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs912306660, COSV65619459; called by muse, mutect2, varscan2
- GGT5 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307686843; called by muse, mutect2, varscan2
- GLI3 | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 86/400 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.948); catalogued as rs1249732177, COSV67891484; called by mutect2, varscan2
- GLT1D1 | c.800C>T p.P267L (on ENST00000442111 / NM_001366889.1; = p.P187L on NM_144669.3) | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as rs145561721; called by muse, mutect2, varscan2
- GSDMC | c.53G>A p.S18N | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.146); catalogued as rs753588428; called by muse, mutect2
- IGKV1-5 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 156/447 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs367799323; called by muse, mutect2, varscan2
- IL13RA1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100861753; called by muse, mutect2
- IRF2BP1 | c.448G>C p.A150P | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs1233253484; called by muse, mutect2, varscan2
- JAK2 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as rs770579392, COSV67690791; called by muse, mutect2, varscan2
- KCNC3 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); catalogued as rs748015812, COSV100979370; called by muse, mutect2
- KCNC3 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 186/892 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100979138; called by muse, mutect2, varscan2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 48/122 reads (39%) | catalogued as rs766469179, COSV56415804; called by mutect2, pindel, varscan2
- KCTD3 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV52069725; called by muse, mutect2, varscan2
- KCTD9 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55341462, COSV99648783; called by muse, mutect2, varscan2
- KIF19 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs534125965; called by muse, mutect2, varscan2
- LMX1A | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149908681, COSV54227573; called by muse, mutect2, varscan2
- MAGEB6 | c.592_594del p.K198del | In Frame Del (DEL) | VAF 40/306 reads (13%) | catalogued as rs1569256566; called by pindel, varscan2
- MARK2 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 56/297 reads (19%) | catalogued as COSV59282412; called by muse, mutect2, varscan2
- MMP7 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs542899524, COSV52772100; called by muse, mutect2, varscan2
- MRO | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370546021; called by muse, mutect2
- MUC19 | c.424dup p.Y142Lfs*3 | Frame Shift Ins (INS) | VAF 32/94 reads (34%) | catalogued as rs776041179; called by mutect2, varscan2
- MZT2A | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as rs1170201907; called by muse, mutect2, varscan2
- NBEA | c.6524C>T p.T2175M | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1405928095, COSV59780924; called by muse, mutect2, varscan2
- NKRF | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs949255431; called by muse, mutect2
- NPDC1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs746975730, COSV58664861; called by muse, mutect2, varscan2
- NRK | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 99/465 reads (21%) | catalogued as rs762084637, COSV54589566, COSV54599067; called by muse, mutect2, varscan2
- NRSN2 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs527597656, COSV66526990; called by muse, mutect2, varscan2
- NTM | c.528G>A p.A176= | Splice Region (SNP) | VAF 33/161 reads (20%) | catalogued as rs183795743, COSV66177690; called by muse, mutect2, varscan2
- NUBP2 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV51906428; called by muse, mutect2
- PAK4 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1052399906; called by muse, mutect2
- PCDH10 | c.926G>T p.R309I | Missense Mutation (SNP) | VAF 82/435 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99993961; called by muse, mutect2, varscan2
- PCDH10 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 124/524 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV52093884, COSV52101365; called by muse, mutect2, varscan2
- PHF21B | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1257044699, COSV100503829, COSV57562990; called by muse, mutect2, varscan2
- PISD | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as rs1285003785; called by muse, mutect2
- PLEKHM2 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104424786; called by muse, mutect2, varscan2
- POMT2 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199719668, COSV99836356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEJ | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 67/568 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.097); catalogued as COSV68640941; called by mutect2, varscan2
- PRSS55 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.033); catalogued as rs569722097, COSV60807921, COSV60809253; called by muse, mutect2, varscan2
- RBBP7 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV66300815; called by muse, mutect2
- RDH14 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1308023907, COSV58399668; called by muse, mutect2
- REM1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52430257; called by muse, mutect2, varscan2
- RGS9 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 34/558 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs1271937692, COSV99287630; called by muse, mutect2
- RIOX1 | c.1197dup p.P400Sfs*9 | Frame Shift Ins (INS) | VAF 97/342 reads (28%) | catalogued as rs1566820607; called by mutect2, pindel, varscan2
- ROBO2 | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs372105678; called by muse, mutect2, varscan2
- SCGB2B2 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as rs138254432, COSV101002817; called by muse, mutect2, varscan2
- SGIP1 | c.1478G>T p.S493I | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52767000; called by muse, mutect2, varscan2
- SH3RF3 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.388); catalogued as rs1427855276, COSV58692354; called by muse, mutect2
- SIX3 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 139/638 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs756395470; called by muse, mutect2, varscan2
- SLC43A3 | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61451359; called by muse, mutect2, varscan2
- SMARCA4 | c.2539C>T p.Q847* | Nonsense Mutation (SNP) | VAF 137/669 reads (20%) | catalogued as COSV60792024; called by muse, mutect2, varscan2
- ST8SIA4 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 63/203 reads (31%) | PolyPhen probably damaging (0.973); catalogued as rs1412320214, COSV51506099; called by muse, mutect2, varscan2
- STK40 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63734976; called by muse, mutect2, varscan2
- SUSD5 | c.1652C>A p.A551E | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.676); catalogued as rs754575197; called by muse, mutect2, varscan2
- TMIGD1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs748902182, COSV61028566; called by muse, mutect2, varscan2
- TRIM49D1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1324597243; called by mutect2, varscan2
- TSPAN11 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.67); catalogued as rs200929072, COSV53819139; called by muse, mutect2, varscan2
- TTN | c.13261C>T p.R4421* (on ENST00000591111; = p.R4375* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 85/402 reads (21%) | catalogued as COSV60084891; called by muse, mutect2, varscan2
- VPS13D | c.7615C>G p.Q2539E | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV50693481; called by muse, mutect2, varscan2
- WASF1 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs377750682; called by muse, mutect2, varscan2
- WNT16 | c.562G>A p.G188R (on ENST00000222462 / NM_057168.2; = p.G178R on NM_016087.2) | Missense Mutation (SNP) | VAF 63/421 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs780579430, COSV55975362; called by muse, mutect2, varscan2
- ZNF471 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs578040016; called by muse, mutect2, varscan2
- ACIN1 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ACSL3 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ADAMTS20 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 102/450 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ADGRG2 | c.1706G>T p.R569I (on ENST00000379869 / NM_001079858.3; = p.R566I on NM_005756.4) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by mutect2, varscan2
- ADRA1B | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.749); called by muse, mutect2
- AHNAK | c.10906C>T p.P3636S | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMOT | c.1150C>A p.Q384K | Missense Mutation (SNP) | VAF 83/357 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AMTN | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ANK1 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 40/712 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- APC | c.2369_2370del p.R790Tfs*8 | Frame Shift Del (DEL) | VAF 118/462 reads (26%) | called by pindel, varscan2
- ARHGEF40 | c.2806C>T p.R936* | Nonsense Mutation (SNP) | VAF 84/282 reads (30%) | called by muse, mutect2, varscan2
- CCDC130 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC166 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 15/379 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2
- CDH26 | c.1886C>A p.A629E | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CFAP54 | c.3170C>A p.S1057Y | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- COQ8A | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 159/638 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- CPLANE1 | c.8557G>A p.D2853N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRYZL1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DACT3 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DOCK11 | c.1876G>T p.V626F | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DZIP1L | c.1670C>A p.T557N | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); called by mutect2, varscan2
- EFHC2 | c.724A>C p.M242L | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLG2 | c.4141G>T p.E1381* | Nonsense Mutation (SNP) | VAF 46/254 reads (18%) | called by mutect2, varscan2
- FREM3 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- KCNC1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KERA | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDLRAD1 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPIN1 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- LTBP4 | c.1379C>A p.P460Q (on ENST00000308370 / NM_001042544.1; = p.P423Q on NM_003573.2) | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEB5 | c.195T>A p.D65E | Missense Mutation (SNP) | VAF 87/339 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- NCAM2 | c.1346T>A p.L449* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- NCKAP5 | c.3314T>C p.L1105S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.033); called by muse, mutect2
- NPBWR1 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 38/690 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.723); called by muse, mutect2
- NTSR2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, varscan2
- PELO | c.1004G>T p.S335I | Missense Mutation (SNP) | VAF 84/356 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- PHACTR3 | c.1652A>G p.K551R | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PITX2 | c.236C>T p.P79L (on ENST00000354925 / NM_001204397.1; = p.P86L on NM_000325.6) | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.069); called by muse, mutect2
- PLEKHG5 | c.760G>T p.G254W (on ENST00000400915 / NM_001042663.3; = p.G217W on NM_020631.6) | Missense Mutation (SNP) | VAF 96/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PPP1R15A | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 58/287 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRB3 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RIN2 | c.1699A>G p.I567V (on ENST00000255006 / NM_001242581.1; = p.I518V on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- RRM2 | c.1105T>C p.Y369H | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RUNDC3A | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC45A4 | c.697G>A p.V233M (on ENST00000517878 / NM_001286646.2; = p.V182M on NM_001080431.2) | Missense Mutation (SNP) | VAF 187/370 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC6A13 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- SLITRK5 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 146/465 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SMARCD2 | c.1260G>T p.M420I | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SOX11 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SOX9 | c.787_788dup p.R264Afs*16 | Frame Shift Ins (INS) | VAF 76/310 reads (25%) | called by pindel, varscan2
- SYNE1 | c.1342C>A p.Q448K (on ENST00000367255 / NM_182961.4; = p.Q455K on NM_033071.3) | Missense Mutation (SNP) | VAF 99/347 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- TAF1 | c.4307G>A p.S1436N (on ENST00000373790 / NM_138923.4; = p.S1457N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TBC1D4 | c.672C>G p.D224E | Missense Mutation (SNP) | VAF 56/659 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.621); called by muse, mutect2
- TCTN1 | c.858_862del p.Q287Hfs*8 (on ENST00000551590 / NM_001173975.3; = p.Q273Hfs*8 on NM_024549.6) | Frame Shift Del (DEL) | VAF 141/481 reads (29%) | called by mutect2, pindel, varscan2
- TGIF2LX | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 24/672 reads (4%) | called by muse, mutect2
- TIE1 | c.2732-1G>T p.X911_splice | Splice Site (SNP) | VAF 55/155 reads (35%) | called by muse, mutect2, varscan2
- TMC7 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- UNC80 | c.1731C>A p.F577L | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UTP18 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, varscan2
- ZNF543 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZNF879 | c.918C>G p.H306Q | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- A2M | c.4137G>A p.A1379= | Silent (SNP) | VAF 80/291 reads (27%) | catalogued as rs374583554; called by muse, mutect2, varscan2
- ABHD8 | c.57C>T p.N19= | Silent (SNP) | VAF 32/180 reads (18%) | catalogued as rs546146109, COSV53113024; called by muse, mutect2, varscan2
- ANO2 | c.30C>A p.G10= (on ENST00000356134 / NM_001278597.3; = p.G14= on NM_001278596.3) | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs1359426146; called by muse, mutect2, varscan2
- ATP6V1B1 | c.750C>T p.N250= | Silent (SNP) | VAF 130/581 reads (22%) | catalogued as rs185606441; called by muse, mutect2, varscan2
- AUTS2 | c.3036C>T p.S1012= | Silent (SNP) | VAF 42/533 reads (8%) | called by muse, mutect2
- BGN | c.765G>T p.L255= | Silent (SNP) | VAF 86/262 reads (33%) | called by mutect2, varscan2
- CASZ1 | c.3138C>T p.D1046= | Silent (SNP) | VAF 75/245 reads (31%) | catalogued as COSV59734376; called by muse, mutect2, varscan2
- CCDC175 | c.1488C>T p.N496= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs199705903, COSV55786527; called by muse, mutect2, varscan2
- DLL3 | c.1767G>A p.T589= | Silent (SNP) | VAF 78/447 reads (17%) | catalogued as COSV52693739; called by muse, mutect2, varscan2
- FOXB2 | c.42G>A p.P14= | Silent (SNP) | VAF 69/348 reads (20%) | catalogued as COSV100942409, COSV65023597; called by muse, mutect2, varscan2
- FOXF2 | c.1278G>T p.S426= | Silent (SNP) | VAF 130/457 reads (28%) | called by mutect2, varscan2
- FUT1 | c.792C>T p.G264= | Silent (SNP) | VAF 30/770 reads (4%) | called by muse, mutect2
- GPATCH8 | c.1665A>G p.L555= | Silent (SNP) | VAF 40/459 reads (9%) | called by muse, mutect2
- HIF1A | c.399T>C p.F133= | Silent (SNP) | VAF 27/178 reads (15%) | called by muse, mutect2, varscan2
- KLF17 | c.15G>A p.P5= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV100954927; called by muse, mutect2, varscan2
- LRP3 | c.1386C>T p.C462= | Silent (SNP) | VAF 74/397 reads (19%) | catalogued as rs368803168; called by muse, mutect2, varscan2
- MAGEA8 | c.792G>A p.A264= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as rs376840959, COSV54063614; called by muse, mutect2, varscan2
- MS4A15 | c.78G>A p.P26= | Silent (SNP) | VAF 75/285 reads (26%) | catalogued as rs575190018, COSV61961235; called by muse, mutect2, varscan2
- MYOM2 | c.1614C>A p.G538= | Silent (SNP) | VAF 38/170 reads (22%) | called by muse, mutect2, varscan2
- NTNG1 | c.201T>C p.P67= | Silent (SNP) | VAF 27/504 reads (5%) | catalogued as COSV53969044; called by muse, mutect2
- OR51S1 | c.81C>T p.G27= | Silent (SNP) | VAF 23/232 reads (10%) | catalogued as COSV59058250; called by muse, mutect2
- P2RX2 | c.531G>A p.P177= (on ENST00000343948 / NM_170683.4; = p.P105= on NM_012226.5) | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as rs748342537; called by muse, mutect2
- PCDHA7 | c.2175G>A p.A725= | Silent (SNP) | VAF 75/343 reads (22%) | catalogued as COSV65335874; called by muse, mutect2, varscan2
- PCDHA8 | c.2205C>A p.G735= | Silent (SNP) | VAF 59/302 reads (20%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1392C>T p.P464= | Silent (SNP) | VAF 24/608 reads (4%) | catalogued as rs1377416102; called by muse, mutect2
- PCDHGA6 | c.993G>A p.A331= | Silent (SNP) | VAF 73/373 reads (20%) | catalogued as rs1338311528, COSV53916232; called by muse, mutect2, varscan2
- PDZRN3 | c.2067C>T p.N689= | Silent (SNP) | VAF 85/486 reads (17%) | catalogued as rs367740961; called by muse, mutect2, varscan2
- PLEKHH1 | c.2364C>G p.L788= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV61285710; called by muse, mutect2, varscan2
- PLXNA1 | c.2331C>T p.N777= | Silent (SNP) | VAF 27/427 reads (6%) | catalogued as rs769684578; called by muse, mutect2
- POMC | c.213C>T p.T71= | Silent (SNP) | VAF 49/218 reads (22%) | catalogued as rs775640407; called by muse, mutect2, varscan2
- PSG3 | c.120C>T p.A40= | Silent (SNP) | VAF 62/276 reads (22%) | catalogued as rs145576404; called by muse, mutect2, varscan2
- PTPN14 | c.2319C>T p.P773= | Silent (SNP) | VAF 88/322 reads (27%) | catalogued as rs201409194; called by muse, varscan2
- PTPRB | c.675G>A p.S225= | Silent (SNP) | VAF 79/352 reads (22%) | catalogued as rs781737365; called by muse, mutect2, varscan2
- PUS7 | c.411C>T p.F137= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs753851280, COSV100708657; called by muse, mutect2, varscan2
- RARB | c.144G>A p.P48= | Silent (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- SLC10A2 | c.291C>T p.A97= | Silent (SNP) | VAF 86/346 reads (25%) | catalogued as rs745423832; called by mutect2, varscan2
- SLC10A7 | c.1062C>T p.I354= | Silent (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- SLC16A2 | c.105G>T p.P35= | Silent (SNP) | VAF 38/417 reads (9%) | called by muse, mutect2
- SLC5A2 | c.402C>T p.G134= | Silent (SNP) | VAF 168/818 reads (21%) | catalogued as rs750125158; called by muse, mutect2, varscan2
- SLC5A9 | c.954C>T p.S318= | Silent (SNP) | VAF 57/268 reads (21%) | catalogued as rs201721766; called by muse, mutect2, varscan2
- SRR | c.729C>T p.S243= | Silent (SNP) | VAF 90/352 reads (26%) | called by muse, mutect2, varscan2
- STAB1 | c.4302G>A p.S1434= | Silent (SNP) | VAF 74/326 reads (23%) | catalogued as rs199976828; called by muse, mutect2, varscan2
- TAF7L | c.669G>A p.T223= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as rs1489738834, COSV61256507; called by muse, mutect2, varscan2
- TBXT | c.1068C>T p.G356= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs762185412; called by mutect2, varscan2
- TCF4 | c.1608C>T p.D536= | Silent (SNP) | VAF 98/377 reads (26%) | catalogued as rs370405835; called by muse, mutect2, varscan2
- TENM3 | c.4407C>A p.A1469= | Silent (SNP) | VAF 106/463 reads (23%) | catalogued as COSV69313666; called by muse, mutect2, varscan2
- TEX37 | c.399G>A p.P133= | Silent (SNP) | VAF 84/296 reads (28%) | catalogued as rs148580273, COSV57556564; called by muse, mutect2, varscan2
- TMEM192 | c.114T>C p.F38= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.22134G>A p.A7378= (on ENST00000591111; = p.A6451= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs768936623, COSV100633902; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- VGF | c.1287G>A p.R429= | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- VRTN | c.1827G>T p.L609= | Silent (SNP) | VAF 33/139 reads (24%) | called by muse, mutect2, varscan2
- YBX2 | c.822G>A p.P274= | Silent (SNP) | VAF 45/172 reads (26%) | catalogued as rs774610299, COSV50302175; called by muse, mutect2, varscan2
- ABCB7 | chrX:75156675 A>G | 5'Flank (SNP) | VAF 10/207 reads (5%) | called by muse, mutect2
- ABLIM1 | c.1041+2636G>A | Intron (SNP) | VAF 21/100 reads (21%) | catalogued as rs12261639; called by muse, mutect2, varscan2
- AREL1 | chr14:74713083 C>A | 5'Flank (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- ASTN1 | c.1120+231C>A | Intron (SNP) | VAF 46/206 reads (22%) | called by muse, mutect2, varscan2
- BABAM1 | chr19:17282643 G>A | 3'Flank (SNP) | VAF 51/296 reads (17%) | called by muse, mutect2, varscan2
- C5orf38 | c.404+10G>T | Intron (SNP) | VAF 42/186 reads (23%) | called by muse, mutect2, varscan2
- CEP170P1 | n.4007C>A | RNA (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.667-9872G>A | Intron (SNP) | VAF 24/73 reads (33%) | catalogued as rs777433296; called by muse, mutect2, varscan2
- CFAP99 | chr4:2459182 G>A | 5'Flank (SNP) | VAF 36/120 reads (30%) | catalogued as rs1410416352; called by muse, mutect2, varscan2
- CHRNA4 | c.*438C>T | 3'UTR (SNP) | VAF 14/248 reads (6%) | catalogued as rs1383122945; called by muse, mutect2
- CSF2RA | c.647-14C>T | Intron (SNP) | VAF 18/346 reads (5%) | catalogued as rs1227327196; called by muse, mutect2
- EIF3IP1 | n.441C>A | RNA (SNP) | VAF 32/717 reads (4%) | called by muse, mutect2
- ENDOV | c.838+88A>C | Intron (SNP) | VAF 69/220 reads (31%) | called by muse, mutect2, varscan2
- FAM157A | n.362G>A | RNA (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- FAM189B | c.*300G>C | 3'UTR (SNP) | VAF 11/258 reads (4%) | called by muse, mutect2
- GABRB3 | chr15:26773674 G>T | 5'Flank (SNP) | VAF 61/188 reads (32%) | catalogued as COSV54661097; called by muse, mutect2, varscan2
- ITFG1 | chr16:47464037 ins A | 5'Flank (INS) | VAF 92/374 reads (25%) | called by mutect2, pindel, varscan2
- LIMCH1 | c.935+1078G>A | Intron (SNP) | VAF 15/347 reads (4%) | catalogued as rs996528630; called by muse, mutect2
- MTX1 | chr1:155215612 C>T | 3'Flank (SNP) | VAF 30/506 reads (6%) | catalogued as rs750898538; called by muse, mutect2
- NFRKB | c.-21-462G>A | Intron (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- NXN | c.361-70864C>T | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- PSG3 | c.*24T>A | 3'UTR (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- RBPMS | c.528+526C>T | Intron (SNP) | VAF 27/202 reads (13%) | catalogued as rs1258452275; called by muse, mutect2, varscan2
- SGK1 | c.285+89dup | Intron (INS) | VAF 22/138 reads (16%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.*1145C>T | 3'UTR (SNP) | VAF 154/562 reads (27%) | catalogued as rs1261425823; called by muse, mutect2, varscan2
- SPRTN | c.322-3089G>A | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- TMCO1 | c.*1045G>A | 3'UTR (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- ZEB2 | c.-40G>A | 5'UTR (SNP) | VAF 113/443 reads (26%) | called by muse, mutect2, varscan2
